Surgical pathology report (de-identified scan), TCGA case TCGA-A7-A3J0, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-A7-A3J0-01A (Primary Tumor).

[page 1 of 2]
Final Surgical Pathology Report

Procedure:

Diagnosis

A. Sentinel lymph nodes, right axilla, biopsy:

There is no evidence of malignancy in either of 2 lymph nodes.

B. Breast, right, excisional biopsy:

Invasive mucinous type carcinoma, Nottingham grade 1. Fibrocystic changes.

Microscopic Description:

A. There is no evidence of malignancy in either of 2 lymph nodes.

[At the request of some staff oncologists and in keeping with the opinion of some experts in breast pathology, immunohistochemical stains for keratin were not used on the sentinel lymph node sections in this case. These stains can be obtained if desired. Our paraffin blocks are retained for 10 years. (Weaver DL et al. New Engl J Med 364:412, 2011. Schwartz GF et al. Cancer 94(10):2542, 2002)].

B.

Invasive carcinoma:

Histologic type: Invasive mucinous carcinoma

Nottingham grade: 1

Architectural score: 3

Nuclear score: 1

Mitotic score: 1

Mitotic index: 4 mitoses/ 10 HPFs (1 HPF = 1.96 sq. mm)

Tumor size: 2.5 cm

Specimen margins: Negative for malignancy. Carcinoma is focally 1.9 mm from the red (anterior) margin.

Vessel invasion: Absent

Calcification: Absent

Non-tumorous breast: Fibrocystic changes are present including cyst formation, sclerosing adenosis, columnar metaplasia and intraductal epithelial hyperplasia without atypia, benign calcification and apocrine metaplasia.

TNM stage: T2 N0

Prognostic markers: See previous biopsy

Specimen

A. Right axillary sentinel node

B. Right breast biopsy long stitch anterior short stitch superior

Clinical Information

Right breast cancer

Gross Description

Specimen A is received unfixed labeled right axillary sentinel nodes and consists of 2 pieces of yellow and red soft tissue measuring 3.5 x 2.5 x 1 and 2.8 x 2 by 1.3 cm. Sections after fixation. One LN in blocks 1-3, second LN in blocks 4-7

1CD-0-3
carcinoma, invasive mucinous 8480/3
Site: breast, NOS C50.9
lw 12/2/11

[page 2 of 2]
:

Specimen B. is received unfixed labeled right breast biopsy. The specimen is received in a Transpec container and consists of yellow and red piece of soft tissue measuring 8.5 by 7.5 by approximately 3 cm. The external surface of the specimen is inked as indicated below.

Anterior: Red

Posterior: Orange

Lateral: Blue

Medial: Green

Superior: Yellow

Inferior: Black

There is a relatively central mucinous appearing firm tumor measuring 2.2 x 2.5 by approximately 2.5 cm. A portion of the specimen is taken for research purposes as requested. Sections after fixation. RS13

Source: NCI Genomic Data Commons file a602084c-5425-4e2f-a30a-9f2b97e42942 (TCGA-A7-A3J0.A5AED5F0-A144-4615-AF78-539B8523D15F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).